Surgical pathology report (de-identified scan), TCGA case TCGA-ZF-AA56, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Sheffield, specimen TCGA-ZF-AA56-01A (Primary Tumor).

[page 1 of 2]
Specimen Comments

SPECIMEN

- 1 - Bladder, uterus, ovaries, cervix.
- 2 - Bowel nodule.
- 3 - Urethral margin.
- 4 - Left ureteric resection margin.
- 5 - Right ureteric resection margin.

CLINICAL DETAILS

- 1 - Massive invasive Ca Bladder. Radical cystectomy.
- 2 - T3 + bladder cancer. Radical/palliative cystectomy.

MACROSCOPY

- 1 - The specimen comprises bladder measuring 90 supero-inferiorly x 100 transversely x 45 mm anterior-posterior. This is accompanied by uterus, which is 50 mm fundus to os, 45 mm transversely, 30 anterior-posterior. The left fallopian tube is 65 mm long, 5 mm diameter. Left ovary is 15 x 12 x 5 mm. Right fallopian tube is 70 mm long, 3 mm diameter. Right ovary 28 x 14 x 16 mm. A triangular piece of vaginal mucosa also present 60 x 45 mm. On opening the bladder, there is a widely infiltrating tumour on the posterior wall + extending to the dome and the lateral walls, 65 mm supero-inferiorly x 38 mm transverse x up to 30 mm in depth. The tumour is 30 mm from the urethral margin. The tumour infiltrates into the anterior wall of the uterus. The right lateral wall shows a diverticulum 25 mm in diameter.
- 2 - This is a firm piece of fibrofatty tissue, 9 mm, maximum dimension.
- 3 - Mucosa tissue with suture toward one end, 20 x 10 x 6 mm.
- 4 - A segment of ureter 6 mm long and up to 3 mm diameter, with a suture at one end.
- 5 - Segment of ureter, 10 mm long x 5 mm diameter, with suture at one end.

MICROSCOPY

1, 3 -5

This a poorly differentiated (Grade 3) transitional cell carcinoma with extensive squamous differentiation and focal glandular differentiation with signet ring forms.

There is extensive squamous metaplasia of the surface mucosa. Tumour is identified arising from dysplastic epithelium. The macroscopic appearance of tumour infiltration into the uterus (pT4) is confirmed with tumour spread to the outer half of the myometrium of the anterior wall. Vascular invasion is present. No perineural invasion is identified. The tumour is present at the serosal surface at the dome. The urethral and the vaginal resection margins are morphologically normal and clear of tumour. The vaginal mucosa is uninvolved, but tumour extends to within 5 mm. A diverticulum is identified in the right lateral wall. Two lymph nodes identified in the perivesical fat do not show any evidence of metastatic deposit. The ovaries appear unremarkable.

2 - This shows fibrofatty tissue infiltrated by a poorly differentiated carcinoma with features similar to those seen in part 1.

SUMMARY: Radical cystectomy with uterus and both adnexa: Grade 3 transitional cell carcinoma with squamous and grandular differentiation. pT4, pNo.

Ref:

ICD-O-3
Carcinoma, urothelial NOS 8120/3
path
Carcinoma, transitional NOS 8120/3
Site: Bladder, posterior wall C67.4
JAD 11/30/14

[page 2 of 2]
Pathologists -

Source: NCI Genomic Data Commons file 747d1e0b-a959-4b8a-b0fd-78e54eff9666 (TCGA-ZF-AA56.835DF5D1-5F61-4C7A-860B-265F1209DDC9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).